Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6371, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6371-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. PROSTATE

TCGA - G9 - 6371

SPECIMEN(S):

A. PROSTATE

GROSS DESCRIPTION:

A. PROSTATE

Received fresh labeled with the patient's identification and "prostate" is a 33-g resected prostate gland measuring 4 cm from right lateral to left lateral, 3.7 cm from anterior to posterior, and 2.7 cm from apex to base. The capsule is smooth, red, and intact. Ink code: Anterior-orange, apex-red, base-blue, right lateral-green, left lateral-yellow, posterior-black. After removal of the apex and base, the prostate weighs 20 g. It consists of uniform tan parenchyma. The left seminal vesicle is 1.9 x 0.9 x 0.5 cm and the right is 3.4 x 1.6 x 0.8 cm; they are made of cystic tan tissue. The left vas deferens is 2 x 0.6 cm and the right is 1.8 x 0.9 cm; they consist of a tubular tan tissue. Tissue is procured (8 g). Submitted entirely:

- A1: right apex, perpendicular section
- A2: left apex, perpendicular sections
- A3: level 1 right anterior
- A4: level 1, right posterior
- A: level 1, left anterior
- A6: level 1, left posterior
- A7: level 2, right anterior and lateral capsule
- A8: level 2, left posterior and lateral capsule
- A9: level 3, right anterior
- A10: level 3, right posterior
- A11: level 3, left anterior
- A12: level 3, left posterior
- A13: level 4, anterior and right lateral capsule
- A14: level 4, posterior and left lateral capsule
- A15: right mid base, perpendicular sections
- A16: left mid base, perpendicular sections
- A17-A18: right lateral base, perpendicular sections
- A19-A21: left lateral base, perpendicular sections
- A22: base of right seminal vesicle and vas deferens
- A23: base of left seminal vesicle and vas deferens
- A24: right seminal vesicle and vas deferens
- A25: left seminal vesicle and vas deferens

DIAGNOSIS:

- A. PROSTATE, SEMINAL VESICLES, AND VASA DEFERENTIA (RADICAL PROSTATECTOMY):
- PROSTATIC ADENOCARCINOMA, GLEASON SCORE 3 + 3 = 6 INVOLVING THE RIGHT AND LEFT PROSTATE LOBES (APPROXIMATELY 20% OF PROSTATE TISSUE)
- NO EXTRAPROSTATIC EXTENSION IDENTIFIED
- NO DEFINITE ANGIOLYMPHATIC AND PERINEURAL INVASION IDENTIFIED
- TUMOR MICROSCOPICALLY INVOLVES THE LEFT POSTERIOR AND LATERAL SURGICAL MARGIN (LINEAR DISTANCE OF POSITIVE MARGIN: <0.5-MM)
- RIGHT AND LEFT SEMINAL VESICLES AND VAS DEFERENS, NEGATIVE FOR TUMOR
- SEE SYNOPSIS REPORT

SYNOPSIS REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

[page 2 of 2]
Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 20%

Gleason Grade/Sum:: Grade 3 + 3 , Sum 6

High Grade PIN Present: Yes

Perineural Invasion: No

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: No

Bladder Neck Involved: No

Margins Involvement: Yes

Location: Level 2, left posterior and lateral

Linear Distance: Microscopic (<1mm)

Frozen Performed: No

Lymph Nodes: No lymph nodes sampled

Other Pathologic Findings: BPH

Pathological Staging (pTNM): T 2c N x M x

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

Source: NCI Genomic Data Commons file 724f6c6f-da0c-48d2-8325-c707be081764 (TCGA-G9-6371.26034718-F43A-491D-99FB-934D99BA4A6A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).